Surgical pathology report (de-identified scan), TCGA case TCGA-XU-A92Y, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-A92Y-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

MRN:

DOB:

Gender:F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

ICD-3

Thymoma, type B3, malignant
8585/3

Surgical Pathology Consultation Report

Date Anterior mediastinum
QW 4/2/14 @ 38.1

SPECIMEN(S) RECEIVED

1. Mediastinum: anterior mediastinal tumour & wedge of left upper lobe of lung-long stitch left lateral, short stitch superior

DIAGNOSIS

1. Composite resection, anterior mediastinal tumor with portion of left upper lobe:

- a) Thymoma, partially encapsulated, type WHO B3 (See Comment), with
- i) Greatest dimension = 4.5 cm
- ii) Focal tumor necrosis and calcification
- iii) Focal invasion through capsule, into mediastinal soft tissues
- iv) No invasion of lung identified
- b) Lung with focal mucus inspissation and post-obstructive changes
- c) Two mediastinal lymph nodes, negative for tumor (0/2)

COMMENT

Sections show a partially encapsulated tumor composed predominantly of epithelioid cells showing prominent clear vacuoles and minimal nuclear atypia. These are admixed with small numbers of lymphocytes which stain positive for CD1a by immunohistochemistry. The tumor shows areas of infarct-like necrosis and focally invades through the capsule into mediastinal fat. Tumor is seen close to the painted surface of the resection specimen (< 0.1 cm) but seems to be covered by thin connective tissue at this point. There are dense adhesions between the tumor capsule and the visceral pleura of the lung, but invasion of the pleura or lung parenchyma is not identified. The combined morphologic and immunohistochemical features are consistent with a type WHO B3 thymoma, with invasion of mediastinal soft tissue.

The surrounding lung parenchyma shows reactive changes, likely secondary to compression and local effects of the tumor. The lung parenchymal nodule noted grossly (0.4 cm diameter; see Gross Description) microscopically shows small airways with mucus inspissation and surrounding post-obstructive changes, but is negative for tumor.

Status: complete

Page: 1 of 2

[page 2 of 2]
Department of Pathology

Patient Name:
MRN: Service: Collected:
DOB: Visit #: Resulted:
Gender: F Location:
Facility:
Ordering MD:

ELECTRONICALLY VERIFIED BY:

CLINICAL HISTORY

Thymoma

GROSS DESCRIPTION

The specimen container labeled with the patient's name and as "anterior mediastinal tumour and wedge of left upper lobe of lung, long stitch left lateral, short stitch superior", contains a lung wedge with attached brownish-tan mass with fatty adhesions received in 10% buffered formalin. The lung wedge measures 7.0 x 4.0 x 2.0 cm and the attached tissue measures 7.5 x 2.5 x 15.6 cm. The entire specimen weighs 79.0 grams and is painted with silver nitrate. On gross examination, the mass appears to be adherent to the lung wedge. The other side of the mass appears to be covered with a thin membranous tissue. On sectioning, there is presence of a well-circumscribed multiloculated tumour that measures 4.5 x 4.4 x 2.0 cm. The tumour has a variegated yellow to yellow-brown color. On sectioning, there is presence of a well-circumscribed translucent yellow nodule located on the lung parenchyma. This nodule measures 0.4 x 0.4 cm and appears to be separated from the main tumour at a 0.5 cm distance. On further sectioning, no other nodules are identified grossly. Within the fatty tissue, one possible lymph node is identified grossly measuring 0.6 x 0.5 cm. Representative sections are submitted as follows:

- 1A to 1D Representative soft section of tumour in relation to lung and membranous tissue.
- 1E Representative section of the tumour in relation to the lung nodule.
- 1F The rest of the lung nodule in toto.
- 1G and 1H Representative section of the lung parenchyma.
- 1I One possible lymph node bisected.

Status: complete

Source: NCI Genomic Data Commons file 6da04600-e9e5-458c-8dcd-a746bf97e4fe (TCGA-XU-A92Y.91B17025-8C0D-4F00-9687-7FF008CE5036.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).